Somatic mutation profile of tumor specimen TARGET-20-PASVSS-09A (aliquot TARGET-20-PASVSS-09A-01D) from TARGET case TARGET-20-PASVSS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.5 years (6,773 days).
Specimen TARGET-20-PASVSS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fe0c257-0465-4278-9d84-e310eb533035.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASVSS-14A (Bone Marrow Normal), aliquot TARGET-20-PASVSS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76cd4b1f-92fa-47cd-92a8-f76ebd5fa39c

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 2, Splice Site 2, Missense Mutation 1, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEBPA | c.937_939dup p.K313dup | In Frame Ins (INS) | VAF 48/109 reads (44%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, pindel, varscan2
- EP300 | c.3671+1G>A p.X1224_splice | Splice Site (SNP) | VAF 63/141 reads (45%) | catalogued as COSV54327591, COSV99607896; called by muse, mutect2, varscan2
- WT1 | c.661+1G>A p.X221_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as CS045095, COSV60077647, COSV60083608; called by muse, mutect2
- CREBBP | c.3590del p.G1197Dfs*53 | Frame Shift Del (DEL) | VAF 23/187 reads (12%) | called by mutect2, pindel, varscan2
- WT1 | c.1070_1076delinsAAGGC p.R357Qfs*15 | Frame Shift Del (DEL) | VAF 44/95 reads (46%) | called by muse*, pindel
- NRXN1 | c.-180C>T | 5'UTR (SNP) | VAF 33/169 reads (20%) | catalogued as COSV68048757; called by muse, mutect2, varscan2
